Gene-level copy-number profile of tumor specimen TCGA-BR-A4CS-01A from TCGA case TCGA-BR-A4CS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-BR-A4CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b4c94f33-4270-4541-b998-d0bac9b25a06.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4CS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c9fa372b-17b2-4e2f-9e3d-fa296d47b811

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 597; copy number 2: 23,337; copy number 3: 21,840; copy number 4: 7,396; copy number 5: 148; copy number 6: 2,887; copy number 7: 1,842; copy number 8: 404; copy number 9: 930; copy number 10: 22; copy number 14: 91; copy number 15: 3; copy number 22: 55; copy number 24: 52; copy number 26: 4; copy number 27: 4; copy number 29: 33; copy number 30: 24; copy number 32: 9; copy number 33: 25; copy number 39: 27; copy number 41: 25; copy number 42: 25; copy number 63: 3; copy number 66: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4CS-01A-11D-A24C-01): tumor purity 0.42, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,625 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,695,535–106,788,148, 3 genes, copy number 63 (within-gene range 3–63): LINC02526, LINC02532, RNU6-117P.
- chr7:70,972–65,554,744, 1,212 genes, copy number 7–9 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7 (broad region; genes not listed).
- chr11:6,016,996–6,360,454, 19 genes, copy number 10–29 (within-gene range 2–29): RNA5SP329, OR56A1, OR56A7P, OR52L2P, OR52X1P, OR56B4, AC022762.1, OR56B3P, OR52B1P, OR52B2, OR52W1, AC022762.2, C11orf42, FAM160A2, CNGA4, CCKBR, AC068733.2, CAVIN3, AC068733.3.
- chr11:10,812,074–12,089,441, 23 genes, copy number 29 (within-gene range 2–29): ZBED5, ZBED5-AS1, AC069360.1, LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2.
- chr11:44,885,903–46,386,608, 42 genes, copy number 27–66: TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:46,428,653–46,429,150, 1 gene, copy number 39: AC024293.1.
- chr11:67,006,778–69,018,447, 91 genes, copy number 6–41 (broad region; genes not listed).
- chr11:69,147,228–69,775,341, 16 genes, copy number 24: AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr11:91,794,319–91,993,255, 3 genes, copy number 32: LINC02756, TUBB4BP4, AP002799.1.
- chr11:94,377,316–94,532,123, 6 genes, copy number 32: GPR83, MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97.
- chr16:21,238,874–90,222,851, 1,788 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr17:41,513,745–41,966,503, 25 genes, copy number 33: KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25.
- chr17:45,393,902–45,895,680, 24 genes, copy number 30 (within-gene range 3–30): ARHGAP27, AC003070.1, PLEKHM1, AC091132.2, MIR4315-1, LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1, DND1P1, AC126544.2, AC126544.1, MAPK8IP1P2, RPS26P8, LINC02210, LINC02210-CRHR1, AC217774.1, AC217774.2, CRHR1, MAPT-AS1, SPPL2C.
- chr17:56,368,063–57,684,689, 29 genes, copy number 5 (within-gene range 3–5): AC006600.1, AC006600.2, RPL39P33, NOG, C17orf67, AC106858.1, DGKE, TRIM25, RNU6-1158P, AC015912.2, AC015912.1, MIR3614, AC015912.3, COIL, AC004584.1, AC004584.2, SCPEP1, AC004584.3, RNF126P1, AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3.
- chr18:47,390–270,278, 9 genes, copy number 7: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1.
- chr18:30,713,275–47,282,939, 213 genes, copy number 14–42 (broad region; genes not listed).
- chr18:47,380,496–47,380,565, 1 gene, copy number 42: MIR4527.
- chr20:87,250–64,313,132, 1,439 genes, copy number 5–10 (broad region; genes not listed).
- chr21:17,210,469–17,296,596, 2 genes, copy number 5: NEK4P1, AP000457.1.
- chr21:22,882,582–23,490,724, 12 genes, copy number 6: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.
- chr21:25,880,550–27,448,579, 18 genes, copy number 6 (within-gene range 1–6): APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1.
- chr21:27,420,380–27,675,024, 3 genes, copy number 6 (within-gene range 1–6): RPL10P1, NCSTNP1, LINC01673.
- chr21:30,741,780–31,063,168, 11 genes, copy number 5: KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1, KRTAP8-2P, KRTAP8-3P, KRTAP8-1, KRTAP7-1, KRTAP11-1, KRTAP19-8, UBE3AP2.
- chr21:32,728,097–33,588,706, 32 genes, copy number 5: PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON.
- chr21:33,589,341–33,643,926, 1 gene, copy number 5: CRYZL1.
- chr21:36,131,767–36,175,815, 1 gene, copy number 5 (within-gene range 1–5): CBR3-AS1.
- chr21:36,156,782–36,320,670, 4 genes, copy number 5: DOP1B, RPL3P1, SRSF9P1, AP000692.2.
- chr21:38,121,451–38,747,460, 11 genes, copy number 5: DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114.
- chr21:38,974,429–39,529,855, 26 genes, copy number 5: LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1.
- chr21:42,311,667–42,447,684, 6 genes, copy number 5: TFF3, TFF2, TFF1, TMPRSS3, UBASH3A, RNU6-1149P.
- chr21:45,073,853–45,625,675, 20 genes, copy number 5 (within-gene range 1–5): ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2.

Autosomal genes at a single copy (total copy number 1): 597. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
